Somatic mutation profile of tumor specimen HCM-CSHL-0366-C50-86A (aliquot HCM-CSHL-0366-C50-86A-01D-A85C-36) from HCMI case HCM-CSHL-0366-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.9 years (17,140 days).
Specimen HCM-CSHL-0366-C50-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26677c0a-7813-41a8-ba54-ae069543ad19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0366-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0366-C50-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e07c72ac-55d6-4a68-92b7-ae18cc03456a

The open-access MAF lists 144 somatic variants for this specimen: 103 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 26, Intron 10, Nonsense Mutation 5, 5'UTR 2, Splice Site 2, RNA 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 308/435 reads (71%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 349/349 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BHLHE22 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 580/886 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1296848862, COSV58861327, COSV58863066; called by muse, varscan2
- BRCC3 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 240/549 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57461779; called by muse, mutect2, varscan2
- CCSER2 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 458/730 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56503909; called by muse, mutect2, varscan2
- CHL1 | c.1408C>T p.R470W (on ENST00000397491 / NM_001253387.1; = p.R486W on NM_006614.4) | Missense Mutation (SNP) | VAF 92/636 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141644867; called by muse, mutect2, varscan2
- COL6A3 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV55115801; called by muse, mutect2, varscan2
- DENND4A | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 113/227 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs756556371; called by muse, mutect2, varscan2
- DIP2A | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 188/393 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs1456031785; called by muse, mutect2, varscan2
- DNAAF3 | c.1354G>A p.A452T (on ENST00000524407 / NM_001256715.2; = p.A499T on NM_178837.4) | Missense Mutation (SNP) | VAF 260/854 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs546293010, COSV61277795; called by muse, mutect2, varscan2
- DNAJC5G | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 167/746 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56081351, COSV56081643; called by muse, mutect2, varscan2
- EME1 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 304/305 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99869077; called by mutect2, varscan2
- EMILIN1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 310/684 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370534632, COSV53154338; called by muse, mutect2, varscan2
- FGF3 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 263/572 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV61925337; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 280/795 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GARS1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs374616031; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM3 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 294/381 reads (77%) | SIFT tolerated (0.87); PolyPhen benign (0.223); catalogued as COSV64471712, COSV64478005; called by muse, mutect2, varscan2
- HMCN1 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 99/597 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as rs1373625415; called by muse, mutect2, varscan2
- KDM6A | c.2995G>C p.E999Q | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65038034, COSV65040758; called by muse, mutect2, varscan2
- KIF13B | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 171/357 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs1277630291; called by muse, mutect2, varscan2
- KIFC1 | c.1401G>C p.E467D | Missense Mutation (SNP) | VAF 258/1246 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65737888; called by muse, mutect2, varscan2
- LYST | c.8003G>A p.R2668K | Missense Mutation (SNP) | VAF 178/350 reads (51%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1416779664; called by muse, mutect2, varscan2
- MUC4 | c.7201C>T p.L2401F | Missense Mutation (SNP) | VAF 414/2961 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as rs752525044; called by muse, varscan2
- MVD | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 212/442 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1177828138, COSV55367769; called by muse, mutect2, varscan2
- NAPA | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 109/237 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs747809065; called by muse, mutect2, varscan2
- NEFH | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 210/493 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1217375234; called by muse, mutect2, varscan2
- NEFH | c.2857G>C p.E953Q | Missense Mutation (SNP) | VAF 184/364 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV60216259; called by muse, mutect2
- NPIPB15 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 212/1323 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as rs754177956; called by muse, mutect2
- OR5AP2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 247/248 reads (100%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100266315; called by muse, mutect2, varscan2
- PCDHGB1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 152/504 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs202007643; called by muse, mutect2, varscan2
- PIEZO2 | c.6383A>T p.Q2128L | Missense Mutation (SNP) | VAF 131/513 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1228178324, COSV53287407; called by muse, mutect2, varscan2
- PILRA | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 181/392 reads (46%) | catalogued as rs1475095141; called by muse, mutect2, varscan2
- PLVAP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 212/440 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs148432183, COSV53086417; called by muse, mutect2, varscan2
- POLQ | c.7321C>T p.Q2441* | Nonsense Mutation (SNP) | VAF 269/409 reads (66%) | catalogued as rs777186145, COSV99953238; called by muse, mutect2, varscan2
- POM121L2 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 170/735 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV66277434; called by muse, mutect2, varscan2
- RAD51C | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 103/227 reads (45%) | catalogued as COSV61677447; called by muse, mutect2, varscan2
- RAPGEF6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs1162961940, COSV99726095; called by muse, mutect2, varscan2
- RBBP4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 120/222 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV65132517; called by muse, mutect2, varscan2
- RBM23 | c.412G>A p.G138R (on ENST00000359890 / NM_001077351.2; = p.G122R on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100321327; called by muse, mutect2, varscan2
- RPS6KA2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 142/324 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as rs1446087210, COSV101551551; called by muse, mutect2
- SERPINE3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 212/414 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV68546061; called by muse, mutect2, varscan2
- SHISA9 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 54/401 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1321323622; called by muse, mutect2, varscan2
- SLC12A2 | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 97/360 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV52475281; called by muse, mutect2, varscan2
- SOX6 | c.1440C>G p.I480M (on ENST00000528429 / NM_001145819.2; = p.I453M on NM_017508.3) | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1464496710, COSV99074036; called by muse, mutect2, varscan2
- SYNE1 | c.2360C>T p.A787V (on ENST00000367255 / NM_182961.4; = p.A794V on NM_033071.3) | Missense Mutation (SNP) | VAF 134/276 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs147406318, COSV54951838; called by muse, mutect2, varscan2
- TBX2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs1433871216; called by muse, mutect2, varscan2
- TBX2 | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 366/757 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV104383109; called by muse, mutect2, varscan2
- TEX49 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 101/201 reads (50%) | catalogued as rs767354203; called by muse, mutect2, varscan2
- ZFYVE26 | c.6005G>A p.C2002Y | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61328817; called by muse, mutect2, varscan2
- ZNF423 | c.2302C>A p.R768S (on ENST00000563137 / NM_001379286.1; = p.R760S on NM_015069.4) | Missense Mutation (SNP) | VAF 191/420 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52183452; called by muse, mutect2, varscan2
- ZNF469 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 237/486 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1430171586; called by muse, mutect2, varscan2
- AAAS | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAM2 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 193/526 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ADGRG6 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- BARX1 | c.98A>C p.E33A | Missense Mutation (SNP) | VAF 61/741 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- CACHD1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 76/528 reads (14%) | called by muse, mutect2, varscan2
- CAT | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCDC3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 323/672 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CNGA1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 107/201 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- CNGB1 | c.3254G>C p.R1085T | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL15A1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CREB3L3 | c.1301A>T p.Q434L | Missense Mutation (SNP) | VAF 46/754 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2
- CT83 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 113/228 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CUL9 | c.7486G>C p.E2496Q | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CYP3A4 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by mutect2, varscan2
- DAGLB | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKG | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 201/606 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DPYS | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 260/893 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPB41L4B | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EXOSC8 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM189A1 | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- FBXO4 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FERMT1 | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 294/587 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FLNA | c.7769T>A p.L2590Q (on ENST00000369850 / NM_001110556.2; = p.L2582Q on NM_001456.3) | Missense Mutation (SNP) | VAF 228/800 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HHIPL1 | c.1814-1G>A p.X605_splice | Splice Site (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
- IMPG1 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 167/554 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- INAVA | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 58/1129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- JRK | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 225/668 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- KIF27 | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MAPK9 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 173/528 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MID1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 136/451 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NAA16 | c.2176C>G p.P726A | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- NAA16 | c.2260C>G p.L754V | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.362); called by muse, varscan2
- NCAPD3 | c.660A>T p.L220F | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NPM3 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OLFML2A | c.1689G>C p.E563D | Missense Mutation (SNP) | VAF 211/432 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PCDHB6 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 162/541 reads (30%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 185/1605 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAP1GDS1 | c.1103G>A p.R368K (on ENST00000408927 / NM_001100427.2; = p.R369K on NM_021159.5) | Missense Mutation (SNP) | VAF 97/407 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RELN | c.9716G>A p.G3239E | Missense Mutation (SNP) | VAF 89/471 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RPA4 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 300/301 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SERTAD3 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 218/484 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC6A16 | c.1329T>G p.N443K | Missense Mutation (SNP) | VAF 231/706 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SOS2 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 95/482 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SPDYE1 | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 98/449 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- STAG1 | c.3073T>G p.Y1025D | Missense Mutation (SNP) | VAF 93/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TRMT10B | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 152/284 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TTC38 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 19/390 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.136); called by muse, mutect2
- TTN | c.63860C>A p.P21287Q (on ENST00000591111; = p.P13863Q on NM_003319.4) | Missense Mutation (SNP) | VAF 28/328 reads (9%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- WDFY3 | c.8917C>T p.H2973Y | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF665 | c.309G>T p.E103D (on ENST00000600412; = p.E168D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF780A | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 219/230 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF800 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, varscan2
- ATP2A1 | c.987G>A p.K329= | Silent (SNP) | VAF 175/356 reads (49%) | called by muse, mutect2, varscan2
- CATSPERD | c.1713C>A p.G571= | Silent (SNP) | VAF 154/313 reads (49%) | called by muse, mutect2, varscan2
- COL15A1 | c.1608G>A p.L536= | Silent (SNP) | VAF 168/409 reads (41%) | called by muse, mutect2, varscan2
- COL6A3 | c.1872C>G p.L624= | Silent (SNP) | VAF 279/279 reads (100%) | catalogued as COSV55086748; called by muse, mutect2, varscan2
- DDX49 | c.531G>A p.P177= | Silent (SNP) | VAF 285/544 reads (52%) | catalogued as rs747220727, COSV53232382; called by muse, mutect2, varscan2
- DHX37 | c.231G>A p.K77= | Silent (SNP) | VAF 151/353 reads (43%) | called by muse, mutect2, varscan2
- DPH2 | c.366C>T p.F122= | Silent (SNP) | VAF 229/1086 reads (21%) | catalogued as rs999912667; called by muse, mutect2, varscan2
- GPR50 | c.168C>T p.N56= | Silent (SNP) | VAF 401/579 reads (69%) | catalogued as rs1246151000; called by muse, mutect2, varscan2
- ISLR2 | c.1374C>T p.R458= | Silent (SNP) | VAF 276/543 reads (51%) | catalogued as rs780483337; called by muse, mutect2, varscan2
- KCNS2 | c.609C>G p.T203= | Silent (SNP) | VAF 204/589 reads (35%) | catalogued as COSV54637866; called by muse, mutect2, varscan2
- LTBP4 | c.591C>A p.L197= (on ENST00000308370 / NM_001042544.1; = p.L160= on NM_003573.2) | Silent (SNP) | VAF 258/546 reads (47%) | called by muse, varscan2
- OSBP | c.2169G>T p.L723= | Silent (SNP) | VAF 450/450 reads (100%) | called by muse, mutect2, varscan2
- PGM1 | c.117C>T p.F39= | Silent (SNP) | VAF 406/1104 reads (37%) | called by muse, mutect2, varscan2
- PRG4 | c.1173C>T p.T391= | Silent (SNP) | VAF 248/1566 reads (16%) | catalogued as COSV63356627; called by muse, mutect2, varscan2
- RAP1GDS1 | c.885C>G p.L295= (on ENST00000408927 / NM_001100427.2; = p.L296= on NM_021159.5) | Silent (SNP) | VAF 95/322 reads (30%) | catalogued as rs369611053; called by muse, mutect2, varscan2
- RFC4 | c.591C>T p.F197= | Silent (SNP) | VAF 116/356 reads (33%) | catalogued as rs1476853269; called by muse, mutect2, varscan2
- SALL4 | c.771G>T p.L257= | Silent (SNP) | VAF 252/1044 reads (24%) | called by muse, mutect2, varscan2
- SERPINA7 | c.426A>T p.P142= | Silent (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2013C>T p.I671= | Silent (SNP) | VAF 124/290 reads (43%) | called by muse, varscan2
- SLC6A12 | c.741C>T p.Y247= | Silent (SNP) | VAF 37/875 reads (4%) | catalogued as rs774671496; called by muse, mutect2
- SPOUT1 | c.579C>T p.I193= | Silent (SNP) | VAF 369/369 reads (100%) | catalogued as rs1205045558; called by muse, mutect2, varscan2
- SSTR4 | c.411C>T p.L137= | Silent (SNP) | VAF 288/1177 reads (24%) | called by muse, mutect2, varscan2
- TEDC1 | c.280C>T p.L94= | Silent (SNP) | VAF 26/574 reads (5%) | catalogued as rs782008482; called by muse, mutect2
- THEMIS | c.1083A>G p.E361= | Silent (SNP) | VAF 678/911 reads (74%) | catalogued as rs1021485276; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1566G>T p.P522= | Silent (SNP) | VAF 104/273 reads (38%) | called by muse, mutect2, varscan2
- ZNF648 | c.1134G>C p.S378= | Silent (SNP) | VAF 188/1184 reads (16%) | catalogued as COSV60572374; called by muse, mutect2, varscan2
- CD19 | c.1085-25C>T | Intron (SNP) | VAF 131/222 reads (59%) | catalogued as rs770883566; called by muse, mutect2, varscan2
- ENDOV | c.-25C>G | 5'UTR (SNP) | VAF 162/341 reads (48%) | called by muse, mutect2, varscan2
- IFT57 | c.494+31_494+33del | Intron (DEL) | VAF 42/120 reads (35%) | called by mutect2, varscan2
- MYO10 | c.-37G>C | 5'UTR (SNP) | VAF 254/612 reads (42%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5892933 G>A | 3'Flank (SNP) | VAF 130/275 reads (47%) | catalogued as rs1051197987, COSV53137420; called by muse, mutect2, varscan2
- NEFH | c.*34G>T | 3'UTR (SNP) | VAF 66/130 reads (51%) | called by muse, mutect2, varscan2
- NUBP2 | c.16+12G>C | Intron (SNP) | VAF 228/761 reads (30%) | catalogued as rs961256046; called by muse, mutect2, varscan2
- PRKAG3 | c.775-43G>A | Intron (SNP) | VAF 134/245 reads (55%) | called by muse, mutect2, varscan2
- RPL12 | c.37+10C>T | Intron (SNP) | VAF 216/457 reads (47%) | catalogued as rs1231047163; called by muse, mutect2, varscan2
- SDHAP2 | n.1083G>C | RNA (SNP) | VAF 80/190 reads (42%) | called by muse, mutect2, varscan2
- SMARCA4 | c.2505+17G>A | Intron (SNP) | VAF 114/244 reads (47%) | called by muse, mutect2, varscan2
- TSC2 | c.3884-54G>A | Intron (SNP) | VAF 83/252 reads (33%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7191G>A | Intron (SNP) | VAF 136/297 reads (46%) | catalogued as rs771535501; called by muse, mutect2, varscan2
- YARS1 | c.1334+48G>C | Intron (SNP) | VAF 74/74 reads (100%) | called by muse, mutect2, varscan2
- ZNF692 | c.-12-196C>T | Intron (SNP) | VAF 147/932 reads (16%) | called by muse, mutect2, varscan2
